Somatic mutation profile of tumor specimen TCGA-04-1347-01A (aliquot TCGA-04-1347-01A-01W-0486-08) from TCGA case TCGA-04-1347, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 81.3 years (29,695 days).
Specimen TCGA-04-1347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a1dbba6-2bc0-4b04-b7f1-83eab27363a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1347-11A (Solid Tissue Normal), aliquot TCGA-04-1347-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b23fc2d-23e1-4847-ac11-edc83bce1efa

The open-access MAF lists 157 somatic variants for this specimen: 120 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 33, Nonsense Mutation 10, Frame Shift Del 4, Intron 2, 5'UTR 2, Translation Start Site 1, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.645T>A p.S215R | Missense Mutation (SNP) | VAF 131/137 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD941799, COSV52752255, COSV52783847, COSV52798196; called by muse, mutect2, varscan2
- ABCA12 | c.5195T>C p.I1732T (on ENST00000272895 / NM_173076.3; = p.I1414T on NM_015657.3) | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV55961133; called by muse, mutect2, varscan2
- ABI1 | c.1312G>T p.G438W | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100697971; called by muse, mutect2
- ADAM29 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664178; called by muse, mutect2, varscan2
- ADAM29 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 121/219 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV63664043; called by muse, mutect2, varscan2
- AGO2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201542441; called by muse, mutect2, varscan2
- AMPD1 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV62416488; called by muse, mutect2, varscan2
- ANP32D | c.335_337del p.L112_E113delins* | Nonsense Mutation (DEL) | VAF 125/212 reads (59%) | catalogued as COSV56980536; called by mutect2, pindel, varscan2
- AURKC | c.781T>G p.S261A (on ENST00000302804 / NM_001015878.2; = p.S227A on NM_003160.3) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57138801; called by muse, mutect2, varscan2
- BAG1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 239/371 reads (64%) | catalogued as rs897821433, COSV65651658; called by muse, mutect2, varscan2
- BAG2 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 60/891 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV58098442; called by muse, mutect2
- BLOC1S2 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV58396340; called by muse, mutect2, varscan2
- BRAF | c.2030C>G p.S677* (on ENST00000288602 / NM_001374244.1; = p.S637* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/176 reads (15%) | catalogued as COSV56199103; called by muse, mutect2, varscan2
- BRAF | c.1460G>T p.S487I (on ENST00000288602 / NM_001374244.1; = p.S447I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV104386540; called by muse, mutect2, varscan2
- BTBD3 | c.653C>G p.T218S | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.442); catalogued as COSV54779525; called by muse, mutect2, varscan2
- C11orf42 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV56411819; called by muse, varscan2
- C15orf48 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV60223381; called by muse, mutect2, varscan2
- CACNA1C | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749561588, COSV59708624; ClinVar: uncertain significance; called by muse, mutect2
- CASP5 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 19/461 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52828125; called by muse, mutect2
- CCDC88A | c.4226A>G p.D1409G | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV55062703; called by muse, mutect2, varscan2
- CCPG1 | c.1697T>C p.F566S | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs1237981539, COSV51242027; called by muse, mutect2, varscan2
- CELA3A | c.552C>A p.D184E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs1055992807; called by muse, mutect2
- CLDN17 | c.144A>T p.E48D | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746697944, COSV54523168; called by muse, mutect2, varscan2
- CPNE6 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53744495; called by muse, mutect2, varscan2
- CSMD1 | c.3266G>A p.G1089E (on ENST00000520002; = p.G1088E on NM_033225.6) | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59331747; called by muse, mutect2, varscan2
- CYP2C18 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 211/1057 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53670655, COSV53672567; called by muse, mutect2, varscan2
- DAGLA | c.2396G>C p.G799A | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as COSV57196576; called by muse, mutect2, varscan2
- DCST2 | c.1169T>G p.I390S | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55052086; called by muse, mutect2, varscan2
- DMXL1 | c.3653C>G p.S1218C | Missense Mutation (SNP) | VAF 191/283 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60707645, COSV60713018; called by muse, mutect2, varscan2
- DNAH10 | c.1460C>A p.A487D (on ENST00000409039; = p.A426D on NM_207437.3) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV68994878; called by muse, mutect2, varscan2
- DNALI1 | c.557A>G p.Y186C (on ENST00000296218; = p.Y164C on NM_003462.5) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV56170117; called by muse, mutect2, varscan2
- DROSHA | c.2789G>C p.R930T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV60776988; called by muse, mutect2, varscan2
- EXOC2 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV57865654; called by muse, mutect2, varscan2
- EYA3 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 121/577 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV65816158, COSV65816805; called by muse, mutect2, varscan2
- FAT1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.997); catalogued as COSV71674420; called by muse, mutect2, varscan2
- FGGY | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58034333; called by muse, mutect2
- FKBP8 | c.662C>G p.A221G (on ENST00000222308 / NM_001308373.2; = p.A222G on NM_012181.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.254); catalogued as COSV55892618; called by mutect2, varscan2
- FREM1 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 88/100 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63087347; called by muse, mutect2, varscan2
- GGT5 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54070454; called by muse, mutect2, varscan2
- GOT1L1 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56875907; called by muse, mutect2
- GRM3 | c.1486T>A p.S496T | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV64472686; called by muse, mutect2, varscan2
- H2BC8 | c.49A>G p.K17E | Missense Mutation (SNP) | VAF 57/451 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.429); catalogued as COSV55127001; called by muse, mutect2, varscan2
- HEPHL1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59892398; called by muse, mutect2, varscan2
- HGD | c.177-1G>C p.X59_splice | Splice Site (SNP) | VAF 60/497 reads (12%) | catalogued as COSV52199812; called by muse, mutect2, varscan2
- HPSE | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 109/585 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.058); catalogued as rs780338532, COSV60987027; called by muse, mutect2, varscan2
- IGSF10 | c.3245C>G p.P1082R | Missense Mutation (SNP) | VAF 66/603 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV56781497, COSV99213320; called by muse, mutect2, varscan2
- INHBE | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 30/465 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350720481; called by muse, mutect2
- KCNH2 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV51125881, COSV51127091; called by muse, mutect2, varscan2
- KRT25 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as COSV56445086; called by muse, varscan2
- LCT | c.2911G>T p.V971L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); catalogued as COSV51550664, COSV51553974; called by muse, mutect2, varscan2
- MEGF10 | c.572G>C p.C191S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57250066; called by muse, mutect2, varscan2
- MFN2 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs545454816, COSV52422850; called by muse, mutect2, varscan2
- MMP7 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52772263; called by muse, mutect2, varscan2
- MMP8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV52632873, COSV99368594; called by muse, varscan2
- MPP4 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59631625; called by muse, mutect2, varscan2
- MRPS18B | c.96_97del p.C33Hfs*6 | Frame Shift Del (DEL) | VAF 69/302 reads (23%) | catalogued as rs749369142; called by mutect2, pindel, varscan2
- MTMR6 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs770125533, COSV67808073; called by muse, mutect2, varscan2
- MYEF2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51048261, COSV51049708; called by muse, mutect2
- MYF6 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV99952803; called by muse, mutect2, varscan2
- NALCN | c.4493G>A p.R1498H | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51935551; called by muse, varscan2
- NCAM2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53078750, COSV53110653; called by muse, mutect2, varscan2
- NEUROD4 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 499/2566 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54471998; called by muse, mutect2, varscan2
- NOTCH4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs1304701623, COSV66681126; called by mutect2, varscan2
- OR10X1 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 51/558 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV63767400; called by muse, mutect2
- OR5K2 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 104/419 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV71143237; called by muse, mutect2, varscan2
- PAK5 | c.1267C>G p.Q423E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV62023084, COSV62028868; called by muse, mutect2, varscan2
- PDGFD | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 40/153 reads (26%) | catalogued as rs756756716, COSV56395135; called by muse, mutect2, varscan2
- PHC3 | c.1067A>C p.Q356P (on ENST00000494943 / NM_001308116.2; = p.Q368P on NM_024947.4) | Missense Mutation (SNP) | VAF 76/772 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV71948781; called by muse, mutect2
- PLEKHA3 | c.55T>A p.W19R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52294501; called by muse, mutect2, varscan2
- PLEKHF2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV59541597; called by muse, mutect2, varscan2
- PTGFR | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 46/276 reads (17%) | catalogued as COSV66115132, COSV66115387; called by muse, mutect2, varscan2
- PZP | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV54361940; called by muse, mutect2, varscan2
- RING1 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63002612; called by muse, mutect2, varscan2
- RNF114 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 36/325 reads (11%) | catalogued as rs773173342, COSV54869485, COSV99724797; called by muse, mutect2, varscan2
- RNF213 | c.6213C>G p.F2071L | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1035740297, COSV60399089; called by muse, mutect2, varscan2
- RNPS1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV57046814; called by muse, mutect2, varscan2
- SEC23A | c.1910T>C p.L637P | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56974592; called by muse, mutect2, varscan2
- SEL1L | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60920783; called by muse, mutect2, varscan2
- SERPINB8 | c.393T>A p.H131Q | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV54639799; called by muse, mutect2
- SLC2A13 | c.1365C>A p.Y455* | Nonsense Mutation (SNP) | VAF 32/231 reads (14%) | catalogued as COSV55118802; called by muse, mutect2, varscan2
- SOX5 | c.2283A>T p.Q761H | Missense Mutation (SNP) | VAF 73/402 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV58631614; called by muse, mutect2, varscan2
- SPINT1 | c.663G>C p.Q221H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59802024; called by muse, varscan2
- SYTL1 | c.1083C>A p.N361K (on ENST00000543823; = p.N349K on NM_032872.3) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58872236; called by muse, mutect2, varscan2
- TBX1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766608075, COSV60353710; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- TLR1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58304534; called by muse, mutect2, varscan2
- TMEM132D | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 116/827 reads (14%) | catalogued as COSV67159738, COSV67160626; called by muse, mutect2, varscan2
- TPO | c.1755C>A p.D585E | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368643878; called by muse, mutect2
- TPX2 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 158/501 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV55920004; called by muse, mutect2, varscan2
- TRIM13 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV53949757; called by muse, mutect2, varscan2
- VEZF1 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 80/87 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs745913326, COSV51969904; called by muse, mutect2, varscan2
- ZFP90 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV68050991; called by muse, mutect2, varscan2
- ZSCAN31 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV60181009; called by muse, mutect2, varscan2
- ADGRF2 | c.1960dup p.I654Nfs*20 (on ENST00000296862 / NM_001368115.2; = p.I586Nfs*20 on NM_153839.7) | Frame Shift Ins (INS) | VAF 29/195 reads (15%) | called by mutect2, pindel, varscan2
- AK9 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.692); called by muse, mutect2
- ATP5PD | c.41T>A p.V14E | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2
- BMS1 | c.3565G>A p.V1189M | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- C12orf42 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DCC | c.1362_1404del p.A455Kfs*9 | Frame Shift Del (DEL) | VAF 60/278 reads (22%) | called by mutect2, pindel
- DNAH9 | c.11080A>C p.K3694Q | Missense Mutation (SNP) | VAF 24/601 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.056); called by muse, mutect2
- DOCK4 | c.4368_4383del p.F1456Lfs*4 | Frame Shift Del (DEL) | VAF 37/261 reads (14%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.11395C>T p.Q3799* | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2
- EGR4 | c.1526G>T p.G509V (on ENST00000545030; = p.G406V on NM_001965.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF2B4 | c.1049G>C p.W350S (on ENST00000347454 / NM_001034116.2; = p.W349S on NM_015636.3) | Missense Mutation (SNP) | VAF 31/870 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- FARP2 | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2A | c.4196G>A p.S1399N | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- NCKAP5 | c.4553del p.P1518Qfs*3 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | called by mutect2, pindel, varscan2
- OR5K4 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 152/1569 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- OR6B2 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR8H3 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OTOGL | c.664T>A p.Y222N (on ENST00000547103; = p.Y213N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLTP | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- POLR1H | c.144G>A p.R48= | Splice Region (SNP) | VAF 13/197 reads (7%) | called by muse, mutect2
- RSBN1 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- RYR2 | c.14840G>T p.R4947M | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SMCHD1 | c.3211T>G p.F1071V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- TGFB1I1 | c.753C>G p.H251Q (on ENST00000394863 / NM_001042454.3; = p.H234Q on NM_015927.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOP2A | c.2427G>A p.M809I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TOR3A | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2
- USP47 | c.4032G>C p.Q1344H (on ENST00000399455 / NM_001372095.1; = p.Q1256H on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.365); called by muse, mutect2
- WDR33 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2
- APP | c.84G>T p.L28= | Silent (SNP) | VAF 61/297 reads (21%) | catalogued as COSV60999187; called by muse, mutect2, varscan2
- ARHGEF11 | c.1425C>T p.A475= | Silent (SNP) | VAF 66/602 reads (11%) | catalogued as rs761961538, COSV63812929; called by muse, mutect2, varscan2
- ASPM | c.7725G>A p.K2575= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV54130819; called by muse, mutect2
- BSND | c.285G>A p.Q95= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV64870735; called by muse, mutect2
- CCT4 | c.1191G>A p.V397= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV66701520; called by muse, varscan2
- CES1 | c.426G>T p.G142= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV62087271; called by muse, mutect2, varscan2
- CHD7 | c.3687T>G p.L1229= | Silent (SNP) | VAF 95/720 reads (13%) | catalogued as COSV71111265; called by muse, mutect2, varscan2
- CHRM3 | c.1290G>A p.Q430= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- CNTNAP2 | c.3339C>T p.H1113= | Silent (SNP) | VAF 72/514 reads (14%) | called by muse, mutect2, varscan2
- CRADD | c.66G>T p.V22= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV60553806; called by muse, mutect2, varscan2
- CUBN | c.5523G>T p.T1841= | Silent (SNP) | VAF 87/505 reads (17%) | catalogued as rs767515084, COSV64715543, COSV64717173; called by muse, mutect2, varscan2
- DNAI2 | c.597C>T p.Y199= | Silent (SNP) | VAF 40/193 reads (21%) | catalogued as COSV56759169; called by muse, mutect2, varscan2
- ESPN | c.1026C>T p.S342= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs753599663; called by muse, mutect2, varscan2
- FCRL1 | c.705T>C p.S235= | Silent (SNP) | VAF 24/216 reads (11%) | catalogued as rs754478993, COSV63825524; called by muse, mutect2, varscan2
- GOLPH3 | c.885G>A p.A295= | Silent (SNP) | VAF 66/335 reads (20%) | catalogued as rs771157837, COSV54061024, COSV54061639; called by muse, mutect2, varscan2
- H4C12 | c.213G>A p.V71= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs764527111; called by muse, mutect2, varscan2
- HMCN1 | c.16410C>T p.C5470= | Silent (SNP) | VAF 72/551 reads (13%) | catalogued as COSV54904850; called by muse, mutect2, varscan2
- HSPG2 | c.11511C>G p.L3837= | Silent (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- IL37 | c.294G>A p.L98= | Silent (SNP) | VAF 290/658 reads (44%) | catalogued as COSV54491350; called by muse, mutect2, varscan2
- KIR2DL1 | c.1035C>A p.V345= | Silent (SNP) | VAF 362/1220 reads (30%) | catalogued as rs765912396; called by muse, mutect2, varscan2
- MYH8 | c.3396A>T p.R1132= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV67966087; called by muse, mutect2, varscan2
- MYSM1 | c.2202A>G p.E734= | Silent (SNP) | VAF 12/307 reads (4%) | called by muse, mutect2
- NR5A1 | c.1299C>A p.A433= | Silent (SNP) | VAF 29/30 reads (97%) | called by muse, mutect2, varscan2
- PHLDB3 | c.1401G>A p.A467= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs373252899; called by muse, mutect2, varscan2
- PIK3CA | c.288A>G p.Q96= | Silent (SNP) | VAF 55/612 reads (9%) | catalogued as rs1307338981; called by muse, mutect2
- REV1 | c.993G>A p.T331= | Silent (SNP) | VAF 35/357 reads (10%) | catalogued as COSV51485897; called by muse, mutect2, varscan2
- ROS1 | c.1677C>A p.G559= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV63856074; called by muse, mutect2, varscan2
- SESN2 | c.1125C>T p.Y375= | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV53427820; called by muse, mutect2, varscan2
- TDRD1 | c.720T>G p.T240= | Silent (SNP) | VAF 33/147 reads (22%) | called by muse, mutect2, varscan2
- USP43 | c.2364G>T p.R788= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV53303193; called by muse, varscan2
- WNT1 | c.162A>G p.Q54= | Silent (SNP) | VAF 34/245 reads (14%) | called by muse, mutect2, varscan2
- ZBTB43 | c.1362C>T p.Y454= | Silent (SNP) | VAF 71/258 reads (28%) | catalogued as rs776691831, COSV65094390; called by muse, mutect2, varscan2
- ZNF398 | c.117A>G p.A39= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV60065443; called by muse, mutect2, varscan2
- CALCR | c.51+2939C>T | Intron (SNP) | VAF 61/271 reads (23%) | catalogued as rs765001549, COSV64008472; called by muse, mutect2, varscan2
- DEFB118 | c.-1C>A | 5'UTR (SNP) | VAF 34/578 reads (6%) | catalogued as COSV99489231; called by muse, mutect2
- SKP2 | c.1062-1542G>A | Intron (SNP) | VAF 92/289 reads (32%) | catalogued as COSV57042518; called by muse, varscan2
- VPS11 | c.-1043C>G | 5'UTR (SNP) | VAF 12/45 reads (27%) | catalogued as COSV56185435; called by muse, mutect2, varscan2
